Gene-level copy-number profile of tumor specimen TCGA-S5-AA26-01A from TCGA case TCGA-S5-AA26, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 46.5 years (16,972 days).
Specimen TCGA-S5-AA26-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.72f3e736-2638-4be4-a7d5-00a2607fea7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S5-AA26-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3a265ac9-9334-42e3-9727-973cc900ad8c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 11,102; copy number 2: 45,382; copy number 3: 3,192; copy number 4: 56; copy number 27: 6; copy number 34: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S5-AA26-01A-11D-A38F-01): tumor purity 0.95, ploidy 3.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:128,067,194–128,581,576, 13 genes: AC108059.2, Y_RNA, UGGT1, SRMP3, AC108059.1, DYNLT3P2, RPL14P6, RPL21P34, HS6ST1, Y_RNA, RNA5SP103, ISCA1P6, AC012451.1.
- chr2:181,422,154–182,523,192, 16 genes (within-gene range 0–1): AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P.
- chr2:201,233,443–201,357,398, 2 genes (within-gene range 0–1): CASP8, FLACC1.
- chr2:224,294,930–224,402,107, 2 genes: AC008072.1, FAM124B.
- chr9:15,524,576–16,410,990, 8 genes: AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92.
- chr9:16,473,188–16,476,237, 1 gene: AL449983.1.
- chr9:21,524,307–22,214,672, 19 genes: SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:59,829,273–60,455,214, 21 genes, copy number 34: CBLIF, TCN1, OOSP3, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A, MS4A4A, MS4A4E, MIR6503, MS4A6E, MS4A7, MS4A14, MS4A5.
- chr11:69,641,156–69,819,416, 6 genes, copy number 27: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.

Autosomal genes at a single copy (total copy number 1): 8,713. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
